Somatic mutation profile of tumor specimen TCGA-HT-7467-01A (aliquot TCGA-HT-7467-01A-11D-2024-08) from TCGA case TCGA-HT-7467, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Brain, NOS; Tumor grade: G2; Age at diagnosis: 54.6 years (19,944 days).
Specimen TCGA-HT-7467-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8371cfbe-996b-40bd-99b5-4ef16ff1a4e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7467-10A (Blood Derived Normal), aliquot TCGA-HT-7467-10A-01D-2024-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f0fe2dd-342e-4c19-91f4-c8fdc2076ac7

The open-access MAF lists 29 somatic variants for this specimen: 24 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 19, Silent 5, Nonsense Mutation 3, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 10/80 reads (13%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADGRF1 | c.1750G>A p.V584I | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as rs188943175, COSV51945384; called by muse, mutect2, varscan2
- AKAP3 | c.547G>A p.V183I | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs140759485; called by muse, varscan2
- ANKRD30A | c.1729C>A p.Q577K (on ENST00000611781; = p.Q521K on NM_052997.2) | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.678); catalogued as COSV64619474; called by muse, varscan2
- AP1G2 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs533882993, COSV58113818; called by muse, mutect2, varscan2
- ARMC3 | c.367G>C p.V123L | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.4); catalogued as COSV53066688; called by muse, mutect2
- CHRM1 | c.1375C>T p.Q459* | Nonsense Mutation (SNP) | VAF 20/131 reads (15%) | catalogued as COSV61007570; called by muse, mutect2
- CTSZ | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as COSV53884702; called by muse, mutect2, varscan2
- DOCK5 | c.1628C>T p.S543L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs781464699, COSV52409924; called by muse, mutect2, varscan2
- ENPP2 | c.774A>T p.Q258H | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50034050; called by muse, mutect2, varscan2
- LAMA3 | c.1570C>T p.R524C | Missense Mutation (SNP) | VAF 26/205 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as rs754718312, COSV58078617; called by muse, mutect2, varscan2
- OR2Z1 | c.407T>C p.M136T | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs566429260, COSV60693210; called by muse, mutect2, varscan2
- OR5A1 | c.497T>C p.I166T | Missense Mutation (SNP) | VAF 48/379 reads (13%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.688); catalogued as COSV57378116; called by muse, mutect2, varscan2
- PADI2 | c.754G>A p.V252M | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs192937557, COSV100971118; called by muse, mutect2, varscan2
- PCSK2 | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 7/67 reads (10%) | catalogued as rs1173212112, COSV52728606; called by muse, mutect2, varscan2
- PLA2G4A | c.319T>G p.F107V | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as COSV66556515; called by muse, mutect2, varscan2
- PTPRH | c.3121C>T p.Q1041* | Nonsense Mutation (SNP) | VAF 7/111 reads (6%) | catalogued as COSV54744915, COSV54749446; called by muse, mutect2
- SAXO1 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.037); catalogued as rs117915008, COSV65871799; called by muse, mutect2, varscan2
- SLC30A8 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs767594541, COSV69973671; called by muse, mutect2, varscan2
- SLCO4C1 | c.1397C>T p.T466M | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs145600550; called by mutect2, varscan2
- UBR5 | c.5324G>A p.S1775N | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.878); catalogued as COSV55298797; called by muse, mutect2, varscan2
- AGO1 | c.1818dup p.P607Tfs*32 | Frame Shift Ins (INS) | VAF 18/81 reads (22%) | called by mutect2, pindel, varscan2
- CACNA1B | c.425G>A p.C142Y | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CIC | c.436_437del p.S146* | Frame Shift Del (DEL) | VAF 5/29 reads (17%) | called by pindel, varscan2
- ANAPC5 | c.1011C>T p.H337= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs782272516, COSV55845115; called by muse, mutect2, varscan2
- CCDC158 | c.165T>C p.P55= | Silent (SNP) | VAF 5/64 reads (8%) | catalogued as COSV66357059; called by muse, mutect2
- PEDS1-UBE2V1 | c.918A>G p.R306= | Silent (SNP) | VAF 22/139 reads (16%) | catalogued as COSV59015580; called by muse, mutect2, varscan2
- REM2 | c.375G>A p.V125= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as COSV57466010; called by muse, mutect2, varscan2
- SLC43A2 | c.432C>T p.S144= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs762945382, COSV56771183; called by muse, mutect2, varscan2
